Somatic mutation profile of tumor specimen ALCH-ABS2-TTP1-A (aliquot ALCH-ABS2-TTP1-A-1-0-D-A489-36) from ALCHEMIST case ALCH-ABS2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 76.0 years (27,772 days).
Specimen ALCH-ABS2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdec11ac-2f0c-4201-ba2a-953108b4f4ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABS2-NB1-A (Blood Derived Normal), aliquot ALCH-ABS2-NB1-A-1-0-D-A489-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/480b7ec0-c74d-451f-ade9-eea9955e6a4a

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 8, Intron 5, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 105/641 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 23/153 reads (15%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ARF1 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV99683326; called by muse, mutect2, varscan2
- CELSR1 | c.4030A>G p.I1344V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.05); catalogued as rs1227053484; called by muse, mutect2, varscan2
- GAREM1 | c.1829C>T p.S610F (on ENST00000269209 / NM_001242409.2; = p.S609F on NM_022751.3) | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV52513837; called by muse, mutect2
- ICE1 | c.2908G>C p.D970H | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV104409457; called by muse, mutect2
- KCNA2 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | catalogued as COSV60369277; called by muse, mutect2
- KCNC2 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54377599; called by muse, mutect2, varscan2
- KDM3B | c.5078A>G p.N1693S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58691403; called by muse, mutect2, varscan2
- LAPTM4B | c.555C>G p.Y185* (on ENST00000445593; = p.Y94* on NM_018407.6) | Nonsense Mutation (SNP) | VAF 26/191 reads (14%) | catalogued as COSV101503494; called by muse, mutect2, varscan2
- MPPED2 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV63898272; called by muse, mutect2, varscan2
- NBPF12 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 38/646 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs1194973724; called by muse, mutect2
- NLRP12 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV60750895; called by muse, mutect2, varscan2
- PRKN | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs529808032, COSV58203788, COSV58274029; called by muse, mutect2, varscan2
- RBMXL3 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.355); catalogued as rs201303575, COSV57750455; called by muse, mutect2
- SYNGR1 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs765177986; called by muse, mutect2, varscan2
- TMX3 | c.1280A>G p.K427R | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs754703577; called by muse, mutect2
- TTN | c.14159C>T p.A4720V (on ENST00000591111; = p.A3793V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/156 reads (10%) | PolyPhen probably damaging (0.997); catalogued as COSV104414470; called by muse, varscan2
- ACTRT1 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- C1orf100 | c.286A>T p.T96S | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.096); called by muse, mutect2
- CNTN1 | c.1339T>C p.S447P | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); called by muse, mutect2
- DMBX1 | c.298A>G p.M100V | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EPHA6 | c.3253G>C p.D1085H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- JCAD | c.1592G>A p.G531D | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.068); called by muse, varscan2
- KDM8 | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 48/514 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.668); called by muse, mutect2
- KLRG2 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.327); called by mutect2, varscan2
- LAMA5 | c.10083G>T p.R3361S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0); called by mutect2, varscan2
- NPHP3 | c.1437T>A p.D479E | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- NRIP1 | c.671A>G p.Q224R | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); called by muse, mutect2
- NXPE2 | c.1328del p.N443Tfs*43 | Frame Shift Del (DEL) | VAF 16/143 reads (11%) | called by mutect2, varscan2
- OR13A1 | c.86A>T p.E29V | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- RNF220 | c.459G>C p.L153F | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SCN9A | c.3085G>C p.D1029H (on ENST00000303354; = p.D1018H on NM_002977.3) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); called by muse, mutect2
- SEZ6L | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 21/186 reads (11%) | called by muse, mutect2, varscan2
- SLC6A5 | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SLC8B1 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMTNL1 | c.931A>C p.N311H (on ENST00000399154; = p.N348H on NM_001105565.2) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- TXNDC16 | c.884G>T p.W295L | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.122); called by muse, mutect2
- WTIP | c.340_341dup p.D115Tfs*187 | Frame Shift Ins (INS) | VAF 5/51 reads (10%) | called by mutect2, pindel
- CASS4 | c.1257C>T p.D419= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs1296930089; called by muse, mutect2
- LRRTM4 | c.1020G>A p.A340= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs1328534247, COSV69140915; called by muse, mutect2, varscan2
- OR8H2 | c.240T>A p.P80= | Silent (SNP) | VAF 16/207 reads (8%) | called by muse, mutect2
- PPM1F | c.1266C>T p.G422= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as rs775944969, COSV54284300; called by muse, mutect2, varscan2
- PTRH2 | c.78C>A p.G26= | Silent (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- PXDNL | c.2068C>A p.R690= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV62494746; called by mutect2, varscan2
- SYNE1 | c.10260G>A p.A3420= (on ENST00000367255 / NM_182961.4; = p.A3427= on NM_033071.3) | Silent (SNP) | VAF 28/356 reads (8%) | catalogued as rs145287138; ClinVar: benign / uncertain significance; called by muse, mutect2
- ZSWIM3 | c.1665A>G p.Q555= | Silent (SNP) | VAF 23/275 reads (8%) | catalogued as rs780757468; called by muse, mutect2
- CCDC6 | c.*258G>A | 3'UTR (SNP) | VAF 43/409 reads (11%) | catalogued as rs761476747, COSV54058530; called by muse, mutect2, varscan2
- CIT | c.4729-427T>G | Intron (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
- GAB1 | c.367+1662G>T | Intron (SNP) | VAF 50/305 reads (16%) | called by muse, varscan2
- GAB1 | c.367+1700G>T | Intron (SNP) | VAF 44/274 reads (16%) | called by muse, varscan2
- GPATCH2L | c.1053-40T>G | Intron (SNP) | VAF 13/295 reads (4%) | called by muse, mutect2
- NBAS | c.1084-5052T>A | Intron (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- RTN3 | c.*42T>G | 3'UTR (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
